Gene-level copy-number profile of tumor specimen TCGA-A3-3313-01A from TCGA case TCGA-A3-3313, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 59.0 years (21,556 days).
Specimen TCGA-A3-3313-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRC.d7a94f98-a887-4725-8b20-c1e759caf149.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A3-3313-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/659784be-89b8-44fd-8f90-93b95ed2b259

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,932; copy number 2: 44,611; copy number 3: 6,986; copy number 4: 127; copy number 5: 14; copy number 7: 25; copy number 8: 35; copy number 9: 5; copy number 10: 19; copy number 11: 18; copy number 13: 38; copy number 17: 8; copy number 18: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A3-3313-01A-02D-1322-01): tumor purity 0.74, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 164 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:39,329,990–39,725,408, 1 gene, copy number 11 (within-gene range 2–11): KIF6.
- chr6:39,553,811–40,715,363, 17 genes, copy number 11: E2F4P1, RNU1-54P, DAAM2, AL592158.1, DAAM2-AS1, MOCS1, TUBBP9, FO393411.1, AL139275.2, TDRG1, LINC00951, AL139275.1, LRFN2, RNU6-250P, AL359475.1, AL033380.1, AL583854.1.
- chr6:41,636,882–42,194,956, 27 genes, copy number 5–17: MDFI, NPM1P51, TFEB, AL035588.1, PGC, AL365205.4, FRS3, AL365205.1, PRICKLE4, TOMM6, USP49, AL365205.3, AL365205.2, AL160163.1, MED20, Y_RNA, BYSL, CCND3, RNU6-761P, AL513008.1, TAF8, AL512274.1, C6orf132, AL096814.1, AL096814.2, GUCA1A, GUCA1B.
- chr6:42,224,931–43,075,095, 28 genes, copy number 7–18 (within-gene range 1–18): TRERF1, AL591473.1, UBR2, RNU6-890P, PRPH2, ATP6V0CP3, TBCC, BICRAL, RPL7L1, C6orf226, AL035587.3, PTCRA, AL035587.2, CNPY3, AL035587.1, RPL24P4, GNMT, PEX6, PPP2R5D, MEA1, KLHDC3, RRP36, AL136304.1, RN7SL403P, CUL7, KLC4, AL355385.2, MRPL2.
- chr6:43,506,969–44,089,288, 23 genes, copy number 7 (within-gene range 1–7): LRRC73, POLR1C, YIPF3, AL355802.3, XPO5, AL355802.1, AL355802.2, POLH, POLH-AS1, GTPBP2, MAD2L1BP, RSPH9, MRPS18A, AL136131.1, AL136131.2, VEGFA, AL136131.3, AL157371.2, LINC02537, AL157371.1, AL109615.3, C6orf223, AL109615.2.
- chr6:45,880,827–50,181,007, 65 genes, copy number 8–13 (broad region; genes not listed).
- chr6:62,460,940–62,611,327, 3 genes, copy number 13: DHFRP5, AL355375.1, AL355375.2.

Autosomal genes at a single copy (total copy number 1): 5,545. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
